Somatic mutation profile of tumor specimen TCGA-HC-8264-01B (aliquot TCGA-HC-8264-01B-11D-2395-08) from TCGA case TCGA-HC-8264, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.7 years (22,177 days).
Specimen TCGA-HC-8264-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45a63803-e0b4-488b-b26f-cfe4e96f0fa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8264-10A (Blood Derived Normal), aliquot TCGA-HC-8264-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96722463-436e-441b-89c8-4af0ddf40822

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 57/81 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs782356392, COSV53990957; called by muse, mutect2, varscan2
- ARPP21 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs199754646, COSV51799772; called by muse, mutect2, varscan2
- CEACAM7 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50073185; called by muse, mutect2, varscan2
- CNTN6 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63175291; called by muse, mutect2, varscan2
- DMD | c.6502G>C p.E2168Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as rs779739455, COSV58918164; called by muse, mutect2, varscan2
- ELOVL3 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199876592, COSV64174566; called by muse, mutect2, varscan2
- EPHB1 | c.2571G>T p.M857I | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67663078; called by muse, mutect2, varscan2
- FNDC1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs776284374, COSV51939875; called by muse, mutect2, varscan2
- GAB2 | c.881C>A p.T294N (on ENST00000361507 / NM_080491.3; = p.T256N on NM_012296.3) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs762862308, COSV60868619; called by muse, mutect2
- GRIK1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs375169701; called by muse, mutect2, varscan2
- GUCY1A2 | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1259379286, COSV56489596; called by muse, mutect2, varscan2
- HROB | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV55369870; called by muse, mutect2, varscan2
- HSPA8 | c.1449T>G p.N483K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV57084313; called by muse, mutect2, varscan2
- IKZF5 | c.294T>G p.I98M | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV64397640; called by muse, mutect2
- KCNN3 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV55218786; called by muse, mutect2, varscan2
- KIF2C | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150935880; called by muse, mutect2, varscan2
- PIGQ | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs752541286, COSV50314907; called by muse, mutect2, varscan2
- SLC16A2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as rs779074769, COSV52085453; called by muse, mutect2, varscan2
- SLC8B1 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52528594; called by muse, mutect2, varscan2
- SLITRK1 | c.257G>C p.S86T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV65676165; called by muse, mutect2, varscan2
- TAAR5 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs756342868, COSV57798988; called by muse, mutect2, varscan2
- TUBB4A | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV51152338, COSV51156741; called by muse, mutect2, varscan2
- ZCCHC14 | c.972G>C p.K324N (on ENST00000268616; = p.K461N on NM_015144.3) | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51886929; called by muse, mutect2, varscan2
- MAPRE1 | c.141del p.F47Lfs*12 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- CEP164 | c.930T>C p.L310= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as COSV54042274; called by muse, mutect2, varscan2
- CKAP5 | c.5292A>G p.L1764= (on ENST00000529230 / NM_001008938.4; = p.L1704= on NM_014756.3) | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV56368939; called by muse, mutect2, varscan2
- GCNT4 | c.579G>A p.E193= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV59280987; called by muse, mutect2, varscan2
- HCFC1 | c.2265C>T p.S755= | Silent (SNP) | VAF 102/149 reads (68%) | catalogued as rs201977456, COSV60073392; called by muse, mutect2, varscan2
- ITSN1 | c.3951C>T p.D1317= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV67157211; called by muse, mutect2, varscan2
- KIF26B | c.3846G>A p.L1282= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV63643598; called by muse, mutect2, varscan2
- SLC13A2 | c.708G>A p.T236= | Silent (SNP) | VAF 71/168 reads (42%) | catalogued as rs782351720, COSV58992541; called by muse, mutect2, varscan2
- TANC1 | c.2493C>G p.A831= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as COSV55089519; called by muse, mutect2, varscan2
- C1orf220 | n.587C>T | RNA (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- DCHS2 | n.3214C>T | RNA (SNP) | VAF 29/86 reads (34%) | catalogued as COSV59728863; called by muse, mutect2, varscan2
